Surgical pathology report (de-identified scan), TCGA case TCGA-06-0140, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0140-01A (Primary Tumor).

[page 1 of 3]
Name:
MRN#:

Sex: male Age:
Histology: GBM

Histology code: MIB: 21%

Tissue Bank:

Surgery Date:

Surgeon:

Hospital:

Surg path#:

Additional Data:
Multiple Biopsy Case

AGE/SEX: M DOB:
SURGERY DATE:
RECEIVE DATE:
PATIENT PHONE NO.

Tissue Amount: 1

Number of Vials: 1

Tissue Loc:

Cells cultured: 1-T25 1-SP

Consent:

PHYSICIAN:
COPY TO:

UPDATED REPORT - SEE
ADDENDUM REPORT/DIAGNOSIS.

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, RIGHT PARIETAL,
EXCISIONAL BIOPSIES:
GLIOBLASTOMA MULTIFORME.
B. BRAIN, RIGHT PARIETAL, EXCISION:
GLIOBLASTOMA MULTIFORME.

SEE COMMENT.

ADDENDUM DIAGNOSIS:
BRAIN, MIB-1 PROLIFERATION INDEX:

[page 2 of 3]
21%.

Operation/Specimen: UPDATED REPORT
- Brain.

Clinical History and Pre-Op Dx: year old
man with recent onset of weakness, has
large white parietal enhancing tumor.

GROSS PATHOLOGY:

A.

SPECIMEN: Right parietal lobe lesion.

FIXATIVE: None.

GENERAL: 0.8 cm. in aggregate, tan-red
soft tissue fragment. Submitted for frozen
section.

INTRAOPERATIVE CONSULTATION,
Frozen section diagnosis: Right parietal
lobe lesion: High grade glioma

SECTIONS: 1 - all submitted.

B.

SPECIMEN: Right parietal lobe lesion
(permanent).

FIXATIVE: None.

GENERAL: Multiple irregular tan-white to
pink soft tissue fragments, 1 x 1 cm. in
aggregate.

SECTIONS: 2-3 - all submitted.

COMMENT: In parts A and B, there is an
astrocytic neoplastic proliferation with
prominent nuclear anaplasia, mitotic
activity, microvascular cellular proliferation,
and necrosis, i.e. a glioblastoma
multiforme.

In part B, the neoplasm has extensive
zones of necrosis.

ADDENDUM REPORT

[page 3 of 3]
IMMUNOHISTOCHEMISTRY:

Immunoperoxidase methods for GFAP and MIB-1 were performed on sections from block #2.

The GFAP depicts profuse gliofibrilogenesis by the neoplastic cells. With the MIB-1, a proliferation index of 21% is determined in the more active areas.

MICROSCOPIC: Blocks 3, slides 3, immunoperoxidase stains 2.

Sample Usage:

Bank data:

Source: NCI Genomic Data Commons file e54074ae-b3c7-46c3-91e9-14ecfe64a7e4 (TCGA-06-0140.A4FAFFC1-1B87-4EF1-ABDF-72C3560F01AA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).